Gene-level copy-number profile of tumor specimen TCGA-BB-A5HU-01A from TCGA case TCGA-BB-A5HU, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 47.9 years (17,502 days).
Specimen TCGA-BB-A5HU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.d1d3a9db-824e-461f-a812-089a97611f92.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BB-A5HU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7b000d52-9daa-424f-ba2b-9042f0fd8956

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 801; copy number 2: 16,685; copy number 3: 31,210; copy number 4: 6,219; copy number 5: 2,489; copy number 6: 1,338; copy number 7: 855; copy number 14: 67; copy number 16: 5; copy number 20: 3; copy number 21: 51; copy number 23: 43; copy number 31: 12; copy number 33: 18; copy number 35: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BB-A5HU-01A-11D-A28Q-01): tumor purity 0.36, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,067 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:52,493,152–53,188,938, 5 genes, copy number 16: AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1.
- chr7:54,676,217–56,882,146, 81 genes, copy number 21–33 (broad region; genes not listed).
- chr8:92,668,660–145,066,685, 855 genes, copy number 7 (broad region; genes not listed).
- chr11:70,187,788–70,436,584, 12 genes, copy number 20–35: ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,647,562, 4 genes, copy number 35: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2.
- chr22:15,290,718–16,904,696, 67 genes, copy number 14 (broad region; genes not listed).
- chr22:45,262,273–46,738,252, 43 genes, copy number 23 (within-gene range 4–23): AL008718.2, AL008718.1, UPK3A, FAM118A, SMC1B, RIBC2, AL021391.1, FBLN1, LINC01589, RNU6-1161P, Z95331.1, ATXN10, MIR4762, Z84478.1, BX324167.2, BX324167.1, WNT7B, BX537318.2, BX537318.1, LINC00899, PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B, PPARA, FP325332.1, CDPF1, PKDREJ, TTC38, GTSE1-DT, GTSE1, TRMU, CELSR1, AL031597.1, AL021392.1, GRAMD4, CERK.

Autosomal genes at a single copy (total copy number 1): 382. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
